Somatic mutation profile of tumor specimen MP2PRT-PAVHBM-TMP1-A (aliquot MP2PRT-PAVHBM-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVHBM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,234 days).
Specimen MP2PRT-PAVHBM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23a2dc17-e53b-4293-b8c9-b9640b9350f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHBM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHBM-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25fa4b8a-c382-4513-b76c-622aa5b215fd

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 7, Nonsense Mutation 1, Frame Shift Ins 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOC3 | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs955965915; called by muse, mutect2
- BCHE | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 37/410 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776750503, COSV52259515; called by muse, mutect2
- CCDC25 | c.90C>G p.I30M | Missense Mutation (SNP) | VAF 60/279 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs542973231; called by muse, mutect2, varscan2
- FILIP1 | c.2786G>C p.S929T | Missense Mutation (SNP) | VAF 34/444 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs1461414201; called by muse, mutect2
- GPR22 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 146/323 reads (45%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.984); catalogued as rs200865278; called by muse, mutect2, varscan2
- IKZF1 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 164/337 reads (49%) | catalogued as COSV58783232; called by muse, mutect2, varscan2
- ITPRID2 | c.773C>G p.S258C | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1319867557; called by muse, mutect2
- NAV3 | c.2951C>T p.S984L | Missense Mutation (SNP) | VAF 24/482 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs1005877698, COSV57058762; called by muse, mutect2
- OTUD7A | c.1977G>C p.E659D (on ENST00000307050 / NM_001382637.1; = p.E652D on NM_130901.3) | Missense Mutation (SNP) | VAF 17/600 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV100192342; called by muse, mutect2
- ASPM | c.3545C>T p.S1182L | Missense Mutation (SNP) | VAF 17/304 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2
- ATP12A | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 11/350 reads (3%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); called by muse, mutect2
- ETV6 | c.349dup p.L117Pfs*37 | Frame Shift Ins (INS) | VAF 145/385 reads (38%) | called by mutect2, pindel, varscan2
- EXOSC7 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 76/505 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MBOAT1 | c.546T>G p.F182L | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- MBP | c.33T>A p.N11K | Missense Mutation (SNP) | VAF 94/228 reads (41%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RTCA | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 52/312 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.048); called by muse, varscan2
- TNC | c.3475G>C p.E1159Q | Missense Mutation (SNP) | VAF 80/193 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ELAVL4 | c.387C>A p.I129= | Silent (SNP) | VAF 13/428 reads (3%) | called by muse, mutect2
- MCM3AP | c.810C>G p.V270= | Silent (SNP) | VAF 110/380 reads (29%) | called by muse, mutect2, varscan2
- PDE3B | c.153C>T p.L51= | Silent (SNP) | VAF 143/777 reads (18%) | catalogued as rs755863175; called by muse, mutect2, varscan2
- PTPDC1 | c.1911C>T p.F637= (on ENST00000375360 / NM_177995.3; = p.F689= on NM_152422.4) | Silent (SNP) | VAF 45/522 reads (9%) | called by muse, mutect2
- SLC2A8 | c.1053G>A p.S351= | Silent (SNP) | VAF 226/488 reads (46%) | catalogued as rs754821992, COSV64895366; called by muse, mutect2, varscan2
- SPTBN4 | c.7521C>G p.L2507= | Silent (SNP) | VAF 19/432 reads (4%) | called by muse, mutect2
- STMN2 | c.495G>A p.A165= | Silent (SNP) | VAF 77/191 reads (40%) | catalogued as rs772336347, COSV55220138; called by muse, mutect2, varscan2
- CPEB1 | c.-66C>G | 5'UTR (SNP) | VAF 25/333 reads (8%) | catalogued as rs957992001; called by muse, mutect2
- CTSA | c.-1+40G>A | Intron (SNP) | VAF 29/1035 reads (3%) | called by muse, mutect2
